Somatic mutation profile of tumor specimen TCGA-60-2715-01A (aliquot TCGA-60-2715-01A-01W-0877-08) from TCGA case TCGA-60-2715, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-60-2715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d594f10-17ab-41f0-87e6-1ef5bdb2cc9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2715-11A (Solid Tissue Normal), aliquot TCGA-60-2715-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c70ecda-b6a4-4c09-91a4-eb5e6a3b4a2a

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Frame Shift Ins 3, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10A | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs750431834, COSV63520534; called by muse, mutect2, varscan2
- ATP6V0A2 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57752806; called by mutect2, varscan2
- C6 | c.655A>G p.K219E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV54720480; called by muse, mutect2, varscan2
- CEP128 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53679173; called by muse, mutect2, varscan2
- CHL1 | c.1652C>T p.S551F (on ENST00000397491 / NM_001253387.1; = p.S567F on NM_006614.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as COSV99852007; called by muse, mutect2
- DGKD | c.1606G>A p.A536T (on ENST00000264057 / NM_152879.3; = p.A492T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV51050276, COSV51088555; called by mutect2, varscan2
- ERV3-1 | c.374A>C p.Q125P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99275370; called by muse, mutect2, varscan2
- GLT1D1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV55889353; called by muse, mutect2, varscan2
- KIAA0232 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as rs757335684; called by muse, mutect2, varscan2
- OR2B11 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1482456884, COSV59511623, COSV59511767, COSV59511827; called by muse, mutect2
- OR4M1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs774999461; called by muse, mutect2, varscan2
- OR52N1 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs866085693, COSV57694137; called by muse, mutect2, varscan2
- RYR2 | c.9619A>T p.N3207Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63719414; called by muse, mutect2, varscan2
- VSTM2L | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868797851, COSV65096265; called by muse, mutect2, varscan2
- ZNF337 | c.1006G>C p.V336L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53323340; called by muse, mutect2, varscan2
- ARNT | c.1783dup p.R595Pfs*9 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by pindel, varscan2
- CASC3 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- GSR | c.1259dup p.I421Yfs*10 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- MAP1B | c.7270C>T p.H2424Y | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PACRG | c.339dup p.D114* | Frame Shift Ins (INS) | VAF 2/16 reads (13%) | called by pindel, varscan2
- SPDYC | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TP53 | c.542_543del p.R181Lfs*4 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- ZNF682 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, varscan2
- CHL1 | c.1653C>T p.S551= (on ENST00000397491 / NM_001253387.1; = p.S567= on NM_006614.4) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1044138492; called by muse, mutect2, varscan2
- CNTRL | c.4800C>T p.D1600= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53050737; called by muse, mutect2, varscan2
- EIF2B5 | c.1188C>T p.N396= (on ENST00000647909; = p.N388= on NM_003907.3) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs775010016, COSV56604814; called by mutect2, varscan2
- HTR3E | c.465C>A p.P155= (on ENST00000415389 / NM_001256613.1; = p.P170= on NM_182589.2) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV58949296; called by muse, mutect2, varscan2
- LINGO4 | c.1539C>T p.D513= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1489497792; called by muse, mutect2, varscan2
- NBEA | c.5826G>T p.L1942= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100080619, COSV59829142; called by muse, mutect2, varscan2
- NLRP4 | c.2268G>A p.L756= | Silent (SNP) | VAF 48/62 reads (77%) | called by muse, mutect2, varscan2
- RIN2 | c.1857G>A p.Q619= (on ENST00000255006 / NM_001242581.1; = p.Q570= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- RNF157 | c.927C>T p.A309= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ZNF251 | c.1158C>T p.F386= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- ATP6V1D | c.*1T>A | 3'UTR (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99370774; called by muse, mutect2, varscan2
